Somatic mutation profile of tumor specimen TCGA-70-6722-01A (aliquot TCGA-70-6722-01A-11D-1817-08) from TCGA case TCGA-70-6722, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 47.4 years (17,328 days).
Specimen TCGA-70-6722-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9aa2d5b0-89b0-428b-951b-2974a7e04301.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-70-6722-10A (Blood Derived Normal), aliquot TCGA-70-6722-10A-01D-1817-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/64d1f905-6be7-419c-bec9-f5dfea14011e

The open-access MAF lists 322 somatic variants for this specimen: 250 protein-altering or splice-affecting, 64 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 214, Silent 64, Nonsense Mutation 16, Frame Shift Del 8, Splice Site 6, Intron 3, Frame Shift Ins 3, RNA 2, Splice Region 2, 5'Flank 2, 3'UTR 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2582T>A p.L861Q | Missense Mutation (SNP) | VAF 186/296 reads (63%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs121913444, COSV51766344, COSV51766618; ClinVar: pathogenic / likely pathogenic / drug response; called by muse, varscan2
- TP53 | c.375+1G>C p.X125_splice | Splice Site (SNP) | VAF 31/96 reads (32%) | hotspot (GDC flag); catalogued as CS951538, COSV52663569, COSV52668477, COSV52702628; called by muse, mutect2, varscan2
- AADAC | c.224C>T p.S75L | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs150521396, COSV51761455; called by muse, mutect2
- ABCB4 | c.369G>T p.L123F | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV55936269; called by muse, mutect2, varscan2
- ABLIM1 | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs147888427; called by muse, mutect2, varscan2
- AC008397.2 | c.1681A>T p.T561S | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53207458; called by muse, mutect2, varscan2
- ACSM2A | c.1440T>G p.N480K (on ENST00000219054; = p.N401K on NM_001308169.2) | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as COSV54585575; called by muse, mutect2, varscan2
- ACTL7A | c.774C>G p.N258K | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.026); catalogued as COSV61776824; called by muse, mutect2, varscan2
- ADAM11 | c.449C>T p.S150F | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52346925; called by muse, mutect2, varscan2
- ADAM2 | c.1675A>T p.R559* | Nonsense Mutation (SNP) | VAF 14/86 reads (16%) | catalogued as COSV55863305; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.874G>T p.D292Y | Missense Mutation (SNP) | VAF 28/209 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.781); catalogued as COSV58444180; called by muse, mutect2, varscan2
- ADGRV1 | c.1765A>G p.K589E | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT tolerated (0.63); PolyPhen benign (0.061); catalogued as COSV67986928; called by muse, mutect2, varscan2
- ADGRV1 | c.4606G>T p.E1536* | Nonsense Mutation (SNP) | VAF 40/155 reads (26%) | catalogued as COSV67986931, COSV67992032; called by muse, mutect2, varscan2
- ALX3 | c.677C>A p.A226D | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV63928867; called by muse, mutect2, varscan2
- AMY2A | c.32G>T p.G11V | Missense Mutation (SNP) | VAF 46/262 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.049); catalogued as COSV101340650; called by muse, mutect2, varscan2
- ANK2 | c.8506C>A p.Q2836K | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV52165601; called by muse, mutect2, varscan2
- APOBEC1 | c.97C>T p.R33C | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs867200012, COSV57548497; called by muse, mutect2, varscan2
- ARHGAP10 | c.170A>T p.Q57L | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.23); catalogued as COSV60600579; called by muse, mutect2, varscan2
- ARHGEF35 | c.1145G>T p.W382L | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.104); catalogued as COSV65312727; called by muse, mutect2, varscan2
- ARID2 | c.1868G>T p.R623L | Missense Mutation (SNP) | VAF 51/215 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.312); catalogued as COSV57605758, COSV57614145; called by muse, mutect2, varscan2
- ARNTL | c.1300A>G p.I434V (on ENST00000403290 / NM_001297719.2; = p.I433V on NM_001178.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as rs761186661, COSV62987008; called by muse, mutect2, varscan2
- ASAP1 | c.1771G>T p.E591* | Nonsense Mutation (SNP) | VAF 20/138 reads (14%) | catalogued as COSV63049537; called by muse, mutect2, varscan2
- BID | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.336); catalogued as rs977477055, COSV100433821; called by muse, varscan2
- BOD1L1 | c.975G>T p.K325N | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50017145; called by muse, mutect2, varscan2
- BRINP1 | c.1093G>T p.G365C | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV56317167; called by muse, mutect2, varscan2
- BRINP3 | c.561C>A p.D187E | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV66526994; called by muse, mutect2, varscan2
- BTK | c.6del p.A3Qfs*2 | Frame Shift Del (DEL) | VAF 30/104 reads (29%) | catalogued as COSV58117209, COSV58118150; called by mutect2, pindel, varscan2
- CACNA1C | c.2294C>A p.A765D | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV59727620; called by muse, mutect2, varscan2
- CACNA1H | c.2220G>C p.W740C | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV61992852; called by muse, mutect2, varscan2
- CCDC60 | c.1611C>A p.S537R | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV59540725, COSV59544971; called by muse, mutect2, varscan2
- CDH8 | c.1106G>T p.R369M | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV100183100, COSV99076727; called by muse, varscan2
- CDH8 | c.1089C>A p.D363E | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV100183102, COSV54899075; called by muse, varscan2
- CERCAM | c.763G>T p.A255S | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.021); catalogued as COSV65711166; called by muse, mutect2, varscan2
- CHD7 | c.8450A>T p.N2817I | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.307); catalogued as COSV71107481, COSV71111544; called by muse, mutect2, varscan2
- CHD8 | c.1646C>T p.S549L (on ENST00000646647 / NM_001170629.2; = p.S270L on NM_020920.4) | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); catalogued as COSV67870858; called by muse, mutect2, varscan2
- CLCNKB | c.690C>G p.H230Q | Missense Mutation (SNP) | VAF 15/174 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV65160755; called by muse, mutect2
- CMTR2 | c.1651dup p.S551Ffs*2 | Frame Shift Ins (INS) | VAF 7/51 reads (14%) | catalogued as rs1379046770; called by mutect2, pindel, varscan2
- CMYA5 | c.3724G>C p.V1242L | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.086); catalogued as COSV71406413; called by muse, mutect2
- CMYA5 | c.4469G>C p.R1490T | Missense Mutation (SNP) | VAF 30/183 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as COSV71406418; called by muse, mutect2, varscan2
- CMYA5 | c.4470G>T p.R1490S | Missense Mutation (SNP) | VAF 30/183 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs765448596, COSV71406423; called by muse, mutect2, varscan2
- CNOT4 | c.1626A>T p.A542= (on ENST00000315544 / NM_001190848.1; = p.A539= on NM_013316.4) | Splice Region (SNP) | VAF 11/72 reads (15%) | catalogued as COSV59653303; called by muse, mutect2, varscan2
- CNTN5 | c.533C>A p.T178N | Missense Mutation (SNP) | VAF 27/246 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.053); catalogued as COSV54307565, COSV99671966; called by muse, mutect2, varscan2
- CNTN6 | c.1577A>T p.D526V | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63174947; called by muse, mutect2, varscan2
- CNTNAP4 | c.1604C>A p.S535Y | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.248); catalogued as COSV56684168, COSV56697086; called by muse, mutect2, varscan2
- CNTNAP5 | c.69A>T p.L23F | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV70489667; called by muse, mutect2, varscan2
- COL3A1 | c.2740C>A p.P914T | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.214); catalogued as COSV58589895, COSV58592894; called by muse, mutect2, varscan2
- COL9A1 | c.1694G>C p.G565A | Missense Mutation (SNP) | VAF 10/117 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57885589; called by muse, mutect2
- CPXCR1 | c.620C>A p.P207H | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV52162695; called by muse, mutect2, varscan2
- CSMD2 | c.3153G>T p.K1051N | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.871); catalogued as COSV53897583, COSV53919721; called by muse, mutect2, varscan2
- CSMD3 | c.11103C>A p.N3701K (on ENST00000297405 / NM_001363185.1; = p.N3532K on NM_052900.3) | Missense Mutation (SNP) | VAF 48/199 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52202330; called by muse, mutect2, varscan2
- CSMD3 | c.9353G>T p.G3118V (on ENST00000297405 / NM_001363185.1; = p.G2949V on NM_052900.3) | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV52202347; called by muse, mutect2, varscan2
- CTNNA3 | c.1582C>A p.Q528K | Missense Mutation (SNP) | VAF 17/145 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.033); catalogued as COSV65590442; called by muse, mutect2, varscan2
- CTSL | c.376G>T p.V126L | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV58245654, COSV58246399; called by muse, mutect2, varscan2
- DCBLD1 | c.824C>T p.S275L | Missense Mutation (SNP) | VAF 23/182 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.065); catalogued as rs760566526, COSV51641991; called by muse, mutect2, varscan2
- DGKI | c.419C>A p.A140E | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as COSV55954207; called by muse, mutect2
- DLC1 | c.1099C>A p.Q367K | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.097); catalogued as rs1452865165, COSV52308185; called by muse, mutect2, varscan2
- DMD | c.1258G>A p.V420I | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV55876988; called by muse, mutect2, varscan2
- DNAH5 | c.1564G>T p.E522* | Nonsense Mutation (SNP) | VAF 35/130 reads (27%) | catalogued as COSV54230614, COSV54246035; called by muse, mutect2, varscan2
- DNAH5 | c.1563G>T p.K521N | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.58); catalogued as COSV54230628; called by muse, mutect2, varscan2
- DNAH9 | c.12457C>A p.P4153T | Missense Mutation (SNP) | VAF 44/152 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52353737, COSV99308871; called by muse, mutect2, varscan2
- DNAI2 | c.610+2T>A p.X204_splice | Splice Site (SNP) | VAF 17/74 reads (23%) | catalogued as COSV56759351; called by muse, mutect2, varscan2
- DNAJB13 | c.932G>T p.R311L | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.693); catalogued as COSV60104859; called by muse, mutect2, varscan2
- DSC3 | c.1103C>A p.A368E | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as COSV64573364; called by muse, mutect2, varscan2
- DZANK1 | c.1000G>T p.G334W (on ENST00000262547 / NM_001099407.1; = p.G135W on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs752130841, COSV99362825; called by muse, mutect2, varscan2
- EEF2 | c.2038G>T p.V680L | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.273); catalogued as COSV58579734; called by muse, mutect2, varscan2
- EFCAB14 | c.964A>T p.K322* | Nonsense Mutation (SNP) | VAF 28/147 reads (19%) | catalogued as COSV64239164; called by muse, mutect2, varscan2
- EGFR | c.2527G>T p.V843L | Missense Mutation (SNP) | VAF 209/304 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as CM082606, COSV51767379, COSV51805324, COSV51807303; called by muse, varscan2
- EML3 | c.667C>T p.R223C | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1192854836, COSV53882892; called by muse, mutect2, varscan2
- ENO3 | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 55/209 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as rs779668930, COSV52777811; called by muse, mutect2, varscan2
- ENPP6 | c.62C>A p.S21Y | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.049); catalogued as COSV57068752; called by muse, mutect2, varscan2
- EPHB1 | c.167G>T p.R56L | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV67653976, COSV67661612, COSV67662917; called by muse, mutect2, varscan2
- ERN2 | c.2276G>C p.G759A | Missense Mutation (SNP) | VAF 77/270 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV55622484; called by muse, mutect2, varscan2
- ESRP1 | c.897A>T p.K299N | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV64410307; called by muse, mutect2, varscan2
- FAAH | c.538G>T p.V180L | Missense Mutation (SNP) | VAF 30/179 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as rs757542565, COSV54544373; called by muse, mutect2, varscan2
- FAM9A | c.73C>A p.Q25K | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.019); catalogued as COSV66813374; called by muse, mutect2, varscan2
- FCHO1 | c.583G>T p.D195Y | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as COSV53181591; called by muse, mutect2, varscan2
- FCRL2 | c.41C>G p.T14S | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.011); catalogued as COSV63837135; called by muse, mutect2, varscan2
- FCRLA | c.447G>T p.R149S (on ENST00000367959; = p.R126S on NM_032738.4) | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.69); PolyPhen benign (0.108); catalogued as COSV52686262, COSV52687344; called by muse, mutect2, varscan2
- FDCSP | c.164C>A p.P55Q | Missense Mutation (SNP) | VAF 68/242 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.045); catalogued as COSV58764663; called by muse, mutect2, varscan2
- FFAR3 | c.217G>T p.V73L | Missense Mutation (SNP) | VAF 41/222 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.11); catalogued as COSV100588254; called by muse, varscan2
- FGD6 | c.2825G>C p.R942T | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV59693805; called by muse, mutect2
- FGF22 | c.448C>T p.R150W | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs748495939, COSV51260908, COSV51261226; called by mutect2, varscan2
- FKBP15 | c.1130C>T p.P377L | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53035692; called by muse, mutect2, varscan2
- FLRT2 | c.1534G>T p.A512S | Missense Mutation (SNP) | VAF 43/148 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.046); catalogued as COSV58143379; called by muse, mutect2, varscan2
- FUBP3 | c.305G>T p.R102L | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100156223; called by muse, mutect2, varscan2
- FUBP3 | c.1025G>T p.G342V | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV60514612; called by muse, mutect2, varscan2
- FYB1 | c.1814G>T p.S605I | Missense Mutation (SNP) | VAF 14/225 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.246); catalogued as COSV60948492; called by muse, mutect2
- GAD2 | c.990C>A p.F330L | Missense Mutation (SNP) | VAF 33/231 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.146); catalogued as COSV52157811, COSV52159220; called by muse, mutect2, varscan2
- GBP2 | c.512G>C p.S171T | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.8); catalogued as COSV65069606; called by muse, mutect2, varscan2
- GK5 | c.501G>T p.Q167H | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as COSV67485908; called by muse, mutect2
- GLI2 | c.252C>A p.H84Q | Missense Mutation (SNP) | VAF 69/177 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV58040273, COSV58043522; called by muse, mutect2, varscan2
- GLI3 | c.2144G>T p.S715I | Missense Mutation (SNP) | VAF 30/284 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV67889422; called by muse, mutect2
- GMEB2 | c.1393G>A p.G465S | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.019); catalogued as rs759958259, COSV56605510, COSV99823805; called by muse, mutect2
- GPNMB | c.689A>T p.Y230F | Missense Mutation (SNP) | VAF 27/170 reads (16%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as COSV51698997, COSV99326330; called by muse, mutect2, varscan2
- GPR15 | c.779T>G p.F260C | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV52520684; called by muse, mutect2, varscan2
- GTF2B | c.766G>T p.A256S | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65137043; called by muse, mutect2, varscan2
- HDAC1 | c.917G>T p.R306L | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as COSV61482093; called by muse, mutect2, varscan2
- HDAC4 | c.2042G>A p.R681K | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61867179; called by muse, mutect2, varscan2
- HIF1A | c.197A>G p.Y66C | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60189558; called by muse, mutect2, varscan2
- HOXA10 | c.133G>C p.G45R | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.808); catalogued as COSV52229102; called by muse, mutect2
- HRH1 | c.226G>T p.V76L | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV67955545; called by muse, mutect2, varscan2
- HSPG2 | c.7567C>T p.R2523C | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.431); catalogued as rs747868706, COSV65969123; called by muse, mutect2, varscan2
- HSPG2 | c.5998-1G>T p.X2000_splice | Splice Site (SNP) | VAF 7/73 reads (10%) | catalogued as COSV65972488; called by muse, mutect2
- IGFBP3 | c.470C>A p.T157K | Missense Mutation (SNP) | VAF 29/179 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.242); catalogued as COSV51872570; called by muse, mutect2, varscan2
- IGHMBP2 | c.378G>C p.L126F | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.503); catalogued as COSV54823002; called by muse, mutect2, varscan2
- IGHMBP2 | c.2676G>T p.K892N | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.722); catalogued as COSV54823010; called by muse, mutect2, varscan2
- IKZF1 | c.1510G>C p.E504Q | Missense Mutation (SNP) | VAF 13/188 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1382145921, COSV58786271, COSV58786865; called by muse, mutect2
- IQCK | c.246G>T p.T82= | Splice Region (SNP) | VAF 27/83 reads (33%) | catalogued as COSV57524053; called by muse, mutect2, varscan2
- KDM4A | c.259A>G p.I87V | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV64959811; called by muse, mutect2, varscan2
- KDM7A | c.2434G>C p.D812H | Missense Mutation (SNP) | VAF 34/329 reads (10%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.38); catalogued as rs769521795, COSV50092106; called by muse, mutect2, varscan2
- KHNYN | c.602A>C p.Q201P | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.278); catalogued as COSV52161254; called by muse, mutect2, varscan2
- KIAA2026 | c.3621G>T p.E1207D | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as COSV67355652; called by muse, mutect2, varscan2
- KIF3B | c.1007G>A p.R336H | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770420525, COSV65227069; called by muse, mutect2, varscan2
- KIF5A | c.1873G>T p.E625* | Nonsense Mutation (SNP) | VAF 11/38 reads (29%) | catalogued as COSV54055431; called by muse, mutect2, varscan2
- KIR3DL1 | c.746C>G p.S249C | Missense Mutation (SNP) | VAF 71/234 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); catalogued as COSV100428756, COSV58497052; called by muse, mutect2, varscan2
- KLRC3 | c.637C>A p.R213S | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT tolerated (0.55); PolyPhen benign (0.006); catalogued as rs569300623, COSV101122906, COSV67250668; called by muse, mutect2, varscan2
- KMT2D | c.4162C>T p.R1388W | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs767110613, COSV56449482; called by muse, mutect2, varscan2
- L3MBTL3 | c.698G>C p.C233S | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs906721951, COSV62386579; called by muse, mutect2, varscan2
- LAMC3 | c.462C>A p.D154E | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.261); catalogued as rs147423784, COSV63092246; called by muse, mutect2, varscan2
- LONP2 | c.1057G>T p.V353L | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV53523090; called by muse, mutect2, varscan2
- LPA | c.4624C>A p.P1542T | Missense Mutation (SNP) | VAF 56/244 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60303184; called by muse, mutect2, varscan2
- LPCAT2 | c.931G>A p.A311T | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV50896285; called by muse, mutect2, varscan2
- LRFN2 | c.983G>A p.R328H | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs371674528; called by muse, mutect2, varscan2
- LRP1B | c.6845C>G p.T2282R | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.368); catalogued as COSV101256232, COSV67230134; called by muse, mutect2, varscan2
- LRRC52 | c.496G>T p.D166Y | Missense Mutation (SNP) | VAF 46/232 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV54232466; called by muse, mutect2, varscan2
- LTBP1 | c.3830C>T p.A1277V (on ENST00000404816 / NM_206943.4; = p.A951V on NM_000627.4) | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.367); catalogued as rs924345606, COSV55380252; called by muse, mutect2
- MAPK6 | c.1036G>T p.E346* | Nonsense Mutation (SNP) | VAF 18/48 reads (38%) | catalogued as COSV55930264; called by muse, mutect2, varscan2
- MISP | c.1738G>T p.E580* | Nonsense Mutation (SNP) | VAF 12/77 reads (16%) | catalogued as COSV53120580; called by muse, mutect2, varscan2
- MMP1 | c.857C>A p.A286D | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59510361, COSV59510626; called by muse, mutect2, varscan2
- MRPL15 | c.808G>C p.A270P | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV52637670; called by muse, mutect2, varscan2
- MUC16 | c.39304C>A p.Q13102K | Missense Mutation (SNP) | VAF 44/232 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1287009015, COSV66692959; called by muse, mutect2, varscan2
- MUC16 | c.12397G>C p.E4133Q | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.782); catalogued as COSV67452699; called by muse, mutect2, varscan2
- MUC17 | c.2852C>A p.T951N | Missense Mutation (SNP) | VAF 64/605 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.313); catalogued as rs373737221, COSV60281298, COSV60291122; called by muse, mutect2, varscan2
- MYH2 | c.946G>T p.V316F | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV55439928; called by muse, mutect2, varscan2
- MYH8 | c.5134G>T p.A1712S | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.113); catalogued as COSV67966389; called by muse, mutect2, varscan2
- MYO18B | c.5466G>T p.E1822D | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs1401384909, COSV59136704; called by muse, mutect2
- NAV3 | c.2864G>T p.G955V | Missense Mutation (SNP) | VAF 49/177 reads (28%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV57084970, COSV99886244; called by muse, mutect2, varscan2
- NCKAP5 | c.4615G>T p.V1539F | Missense Mutation (SNP) | VAF 54/208 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.346); catalogued as COSV58448687; called by muse, mutect2, varscan2
- NCKAP5 | c.583G>T p.E195* | Nonsense Mutation (SNP) | VAF 17/91 reads (19%) | catalogued as COSV58448698; called by muse, mutect2, varscan2
- NDST4 | c.431C>A p.S144* | Nonsense Mutation (SNP) | VAF 23/77 reads (30%) | catalogued as COSV52122512; called by muse, mutect2, varscan2
- NINL | c.3443A>T p.Q1148L | Missense Mutation (SNP) | VAF 17/171 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.32); catalogued as COSV54003662; called by muse, mutect2, varscan2
- NKX3-2 | c.485C>A p.T162N | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV66711714; called by muse, mutect2, varscan2
- NOVA2 | c.17C>G p.P6R | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.884); catalogued as COSV54357756; called by muse, mutect2, varscan2
- NOVA2 | c.16C>A p.P6T | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.641); catalogued as COSV54357768; called by muse, mutect2, varscan2
- NUP153 | c.1364G>T p.R455L | Missense Mutation (SNP) | VAF 38/168 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0.23); catalogued as COSV50450894, COSV50459123; called by muse, mutect2, varscan2
- OCM | c.13G>A p.D5N | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.245); catalogued as rs1205616573, COSV54194564; called by muse, mutect2, varscan2
- OLFML3 | c.1069C>T p.P357S | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1207702168, COSV57435767; called by muse, mutect2, varscan2
- OR2L8 | c.560C>A p.A187D | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV61727025; called by muse, mutect2, varscan2
- OR4N5 | c.797C>G p.P266R | Missense Mutation (SNP) | VAF 56/254 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.481); catalogued as COSV61320747, COSV99048812; called by muse, mutect2, varscan2
- OR6M1 | c.260A>C p.E87A | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV58433876; called by muse, mutect2, varscan2
- OR8U1 | c.356C>A p.A119D | Missense Mutation (SNP) | VAF 18/171 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100164016; called by muse, mutect2, varscan2
- OSTC | c.22C>T p.P8S | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as rs753117010, COSV64232292; called by muse, mutect2, varscan2
- P2RY2 | c.943C>T p.R315C | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.871); catalogued as rs774047775, COSV60776457; called by muse, mutect2, varscan2
- PABPC4 | c.1000G>A p.G334R | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63293444; called by muse, mutect2, varscan2
- PCDHA1 | c.1426A>T p.T476S | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.781); catalogued as COSV65374801; called by muse, mutect2, varscan2
- PCDHA1 | c.1427C>T p.T476M | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV65372487; called by muse, mutect2, varscan2
- PCDHA4 | c.214G>A p.G72R | Missense Mutation (SNP) | VAF 63/217 reads (29%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.014); catalogued as COSV63538581, COSV63542497; called by muse, mutect2, varscan2
- PCDHB15 | c.39A>T p.Q13H | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV50978021; called by muse, mutect2, varscan2
- PCDHGA7 | c.305G>T p.C102F | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53963454; called by muse, mutect2, varscan2
- PCDHGB7 | c.811G>T p.E271* | Nonsense Mutation (SNP) | VAF 14/51 reads (27%) | catalogued as rs767728571, COSV53963466, COSV54064780, COSV99533643; called by muse, mutect2, varscan2
- PCK1 | c.1814C>A p.P605H | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60128761; called by muse, mutect2, varscan2
- PCSK9 | c.271T>A p.S91T | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV56160861; called by muse, mutect2, varscan2
- PDZD7 | c.543-1G>T p.X181_splice | Splice Site (SNP) | VAF 13/39 reads (33%) | catalogued as COSV64646509; called by muse, mutect2, varscan2
- PDZRN4 | c.2494C>T p.P832S (on ENST00000402685 / NM_001164595.2; = p.P574S on NM_013377.4) | Missense Mutation (SNP) | VAF 48/179 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.133); catalogued as COSV54204374; called by muse, mutect2, varscan2
- PIEZO2 | c.6628G>T p.A2210S | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53290438; called by muse, mutect2, varscan2
- PIEZO2 | c.6509C>A p.P2170H | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53290460; called by muse, mutect2, varscan2
- PIK3CA | c.1484A>T p.H495L | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV55937723; called by muse, mutect2, varscan2
- POU5F2 | c.176A>C p.D59A | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV67938397; called by muse, mutect2, varscan2
- PPT2 | c.294G>A p.M98I | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.289); catalogued as COSV52998301, COSV52998559; called by muse, mutect2, varscan2
- PRKG1 | c.1179G>T p.Q393H | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.843); catalogued as rs929692657, COSV64771741; called by muse, mutect2
- PSENEN | c.90G>T p.W30C | Missense Mutation (SNP) | VAF 41/165 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53075300; called by muse, mutect2, varscan2
- PTPRH | c.2407G>A p.E803K | Missense Mutation (SNP) | VAF 23/233 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.03); catalogued as COSV54746308; called by muse, mutect2, varscan2
- PTPRT | c.1930G>C p.E644Q | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.018); catalogued as COSV61987066; called by muse, mutect2, varscan2
- RASAL3 | c.1621G>T p.V541L | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59139880; called by muse, mutect2, varscan2
- RBFOX1 | c.194T>C p.L65P | Missense Mutation (SNP) | VAF 32/195 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.823); catalogued as COSV60962041; called by muse, mutect2, varscan2
- RBM11 | c.827A>G p.K276R | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.714); catalogued as COSV68748150; called by muse, mutect2, varscan2
- RBMXL1 | c.913G>T p.G305C | Missense Mutation (SNP) | VAF 60/282 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV53101777; called by muse, varscan2
- REG1A | c.97C>G p.R33G | Missense Mutation (SNP) | VAF 40/347 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.772); catalogued as COSV52069280, COSV52069979; called by muse, mutect2, varscan2
- RGL1 | c.235G>A p.E79K (on ENST00000360851 / NM_001297672.2; = p.E114K on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/167 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV58987080; called by muse, mutect2, varscan2
- RGS12 | c.2797G>A p.E933K | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV58752804, COSV58752996; called by muse, mutect2, varscan2
- RGS9 | c.1062C>A p.Y354* | Nonsense Mutation (SNP) | VAF 13/79 reads (16%) | catalogued as COSV52226120; called by muse, mutect2, varscan2
- RIMS2 | c.3053G>C p.R1018T (on ENST00000666250 / NM_001348490.2; = p.R826T on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/136 reads (30%) | SIFT tolerated (0.58); PolyPhen benign (0.017); catalogued as COSV51652475; called by muse, mutect2, varscan2
- RIT2 | c.89dup p.V31Sfs*3 | Frame Shift Ins (INS) | VAF 36/174 reads (21%) | catalogued as rs765499217; called by pindel, varscan2
- RNF148 | c.679C>G p.Q227E | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV57366660, COSV57388221; called by muse, mutect2, varscan2
- RP1 | c.1252G>A p.E418K | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.07); catalogued as COSV55118520; called by muse, mutect2, varscan2
- RYR2 | c.3986G>T p.G1329V | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV63689800; called by muse, mutect2, varscan2
- S1PR5 | c.542C>T p.A181V | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.042); catalogued as COSV61013951; called by muse, mutect2
- SH2D3A | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 6/82 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as COSV55586439; called by muse, mutect2
- SHROOM3 | c.3130A>T p.R1044* | Nonsense Mutation (SNP) | VAF 16/50 reads (32%) | catalogued as COSV56031020; called by muse, mutect2, varscan2
- SIGLEC5 | c.1166G>T p.G389V | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55780425; called by muse, mutect2, varscan2
- SLC1A1 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.85); PolyPhen benign (0.02); catalogued as COSV52053900; called by muse, mutect2, varscan2
- SLC2A9 | c.1472G>T p.G491V | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.402); catalogued as rs184184711, COSV53322067; called by muse, mutect2, varscan2
- SMYD1 | c.38C>A p.T13N | Missense Mutation (SNP) | VAF 38/281 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV70225310; called by muse, mutect2, varscan2
- SMYD1 | c.868G>C p.G290R | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as COSV70225313; called by muse, mutect2, varscan2
- SMYD1 | c.895C>G p.Q299E | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV70225315; called by muse, varscan2
- SPARCL1 | c.995C>G p.P332R | Missense Mutation (SNP) | VAF 41/159 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.203); catalogued as COSV56804186; called by muse, mutect2, varscan2
- SPRY3 | c.341G>T p.R114L | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.139); catalogued as COSV57143318, COSV57143487; called by muse, mutect2, varscan2
- ST6GAL2 | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 6/36 reads (17%) | PolyPhen probably damaging (0.999); catalogued as COSV62416038; called by muse, mutect2, varscan2
- SYCP2 | c.4276G>A p.E1426K | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV100697931, COSV62768998; called by muse, mutect2, varscan2
- TAOK3 | c.2096G>A p.R699K | Missense Mutation (SNP) | VAF 47/272 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV66826192; called by muse, mutect2, varscan2
- TAS2R60 | c.665G>T p.R222I | Missense Mutation (SNP) | VAF 49/163 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60331101; called by muse, mutect2, varscan2
- TCEAL5 | c.138del p.K47Rfs*94 | Frame Shift Del (DEL) | VAF 12/26 reads (46%) | catalogued as COSV101013117; called by mutect2, varscan2
- TEX33 | c.746G>T p.G249V (on ENST00000381821 / NM_001163857.2; = p.G164V on NM_178552.4) | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV67822208; called by muse, mutect2, varscan2
- TFB2M | c.649A>G p.I217V | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.336); catalogued as COSV63624983; called by muse, mutect2, varscan2
- TIAM1 | c.569A>T p.Q190L | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.991); catalogued as COSV54554812; called by muse, mutect2, varscan2
- TIMELESS | c.2735G>T p.G912V | Missense Mutation (SNP) | VAF 16/159 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV57512125; called by muse, mutect2, varscan2
- TMEM117 | c.769-2A>G p.X257_splice | Splice Site (SNP) | VAF 22/138 reads (16%) | catalogued as COSV56906592; called by muse, mutect2
- TMEM117 | c.769G>T p.D257Y | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56906606; called by muse, mutect2
- TMEM132B | c.1385C>A p.S462Y | Missense Mutation (SNP) | VAF 82/313 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.232); catalogued as COSV54756067; called by muse, mutect2, varscan2
- TMEM229B | c.58G>A p.G20S | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62538820; called by muse, mutect2, varscan2
- TMEM260 | c.1967G>A p.R656K | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs545798179, COSV55100065; called by muse, mutect2, varscan2
- TNFRSF11B | c.541C>A p.H181N | Missense Mutation (SNP) | VAF 30/205 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.036); catalogued as COSV52071643; called by muse, mutect2, varscan2
- TNNT3 | c.119C>A p.T40N (on ENST00000397301 / NM_001367846.1; = p.T29N on NM_006757.4) | Missense Mutation (SNP) | VAF 42/187 reads (22%) | SIFT tolerated (0.39); catalogued as rs1233477669, COSV53487233; called by muse, mutect2, varscan2
- TPRX1 | c.1051C>A p.P351T | Missense Mutation (SNP) | VAF 49/138 reads (36%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.934); catalogued as COSV59116247, COSV59117303; called by muse, mutect2, varscan2
- TRIM25 | c.1657T>A p.W553R | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV57544499; called by muse, mutect2, varscan2
- TRIO | c.1930G>C p.E644Q | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV60085394; called by muse, mutect2
- TRPS1 | c.983G>A p.G328E (on ENST00000220888 / NM_001330599.2; = p.G341E on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV55232330, COSV55244240; called by muse, mutect2, varscan2
- TUBGCP2 | c.2307G>C p.M769I | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV53305803; called by muse, mutect2, varscan2
- USP20 | c.2642G>C p.G881A | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.484); catalogued as COSV100204879, COSV59614714; called by muse, mutect2
- USP25 | c.1466G>T p.S489I | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.776); catalogued as COSV53485409; called by muse, mutect2, varscan2
- VENTX | c.713G>T p.G238V | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.169); catalogued as COSV58084733; called by mutect2, varscan2
- VWA3A | c.1447A>T p.S483C | Missense Mutation (SNP) | VAF 29/160 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.619); catalogued as COSV55391586; called by muse, mutect2, varscan2
- XDH | c.1456G>T p.V486L | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV65148276, COSV65149250; called by muse, mutect2, varscan2
- YPEL4 | c.251A>T p.D84V | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55518736; called by muse, mutect2
- ZAN | c.5615C>A p.P1872Q | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV61810190; called by muse, mutect2, varscan2
- ZBTB20 | c.482G>T p.G161V (on ENST00000474710 / NM_001164342.2; = p.G88V on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 51/89 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61852988; called by muse, mutect2, varscan2
- ZFHX4 | c.3148G>T p.A1050S | Missense Mutation (SNP) | VAF 51/194 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0.225); catalogued as COSV50971496; called by muse, mutect2, varscan2
- ZFHX4 | c.5062C>A p.P1688T | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV50972083; called by muse, mutect2, varscan2
- ZFP90 | c.1369G>T p.E457* | Nonsense Mutation (SNP) | VAF 33/144 reads (23%) | catalogued as COSV68051006; called by muse, mutect2, varscan2
- ZNF253 | c.923G>C p.R308T | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.109); catalogued as COSV63037426; called by muse, mutect2, varscan2
- ZNF33A | c.1854C>A p.Y618* (on ENST00000458705 / NM_006974.3; = p.Y619* on NM_006954.2) | Nonsense Mutation (SNP) | VAF 11/102 reads (11%) | catalogued as COSV56725513; called by muse, mutect2, varscan2
- ZNF423 | c.232G>T p.D78Y (on ENST00000563137 / NM_001379286.1; = p.D70Y on NM_015069.4) | Missense Mutation (SNP) | VAF 64/246 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV52191445; called by muse, mutect2, varscan2
- ZNF560 | c.1922C>A p.S641Y | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV56868435; called by muse, mutect2, varscan2
- ZNF705A | c.205G>T p.G69* | Nonsense Mutation (SNP) | VAF 32/250 reads (13%) | catalogued as rs1207647028, COSV100828265, COSV100828334; called by mutect2, varscan2
- ZNF708 | c.1517G>T p.C506F | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV63607603; called by muse, mutect2, varscan2
- ZNF831 | c.4856G>T p.G1619V | Missense Mutation (SNP) | VAF 10/121 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); catalogued as COSV64041166; called by muse, mutect2
- ZNF99 | c.1066C>A p.L356I | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1267433487, COSV101233892, COSV68055829; called by muse, mutect2, varscan2
- ZSCAN1 | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.466); catalogued as rs546837948, COSV56603607; called by muse, mutect2, varscan2
- ZSCAN1 | c.801C>G p.H267Q | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.031); catalogued as COSV56605148; called by muse, mutect2, varscan2
- ZSWIM5 | c.2956A>G p.I986V | Missense Mutation (SNP) | VAF 29/164 reads (18%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.77); catalogued as COSV55800666; called by muse, mutect2, varscan2
- ABCA12 | c.3715del p.Y1239Tfs*18 (on ENST00000272895 / NM_173076.3; = p.Y921Tfs*18 on NM_015657.3) | Frame Shift Del (DEL) | VAF 44/161 reads (27%) | called by mutect2, pindel, varscan2
- CCDC65 | c.487del p.Q163Nfs*21 | Frame Shift Del (DEL) | VAF 9/39 reads (23%) | called by mutect2, pindel, varscan2
- COL14A1 | c.2151del p.W717* | Frame Shift Del (DEL) | VAF 21/101 reads (21%) | called by mutect2, pindel, varscan2
- CRYBA1 | c.215+2dup p.X72_splice | Splice Site (INS) | VAF 19/119 reads (16%) | called by mutect2, pindel, varscan2
- HDGFL1 | c.51del p.K18Sfs*2 | Frame Shift Del (DEL) | VAF 11/65 reads (17%) | called by mutect2, pindel, varscan2
- HHIPL2 | c.1133del p.G378Efs*4 | Frame Shift Del (DEL) | VAF 12/72 reads (17%) | called by pindel, varscan2
- IGLJ3 | c.140T>A p.L47Q | Missense Mutation (SNP) | VAF 17/167 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.887); called by muse, mutect2
- MUC16 | c.12608_12609del p.T4203Nfs*24 | Frame Shift Del (DEL) | VAF 17/73 reads (23%) | called by mutect2, pindel, varscan2
- RAD51C | c.313dup p.S105Ffs*5 | Frame Shift Ins (INS) | VAF 13/92 reads (14%) | called by mutect2, pindel, varscan2
- TRBV6-1 | c.245G>T p.G82V | Missense Mutation (SNP) | VAF 60/222 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- ABCC11 | c.990C>T p.H330= | Silent (SNP) | VAF 22/83 reads (27%) | catalogued as rs1006459519, COSV62323677; called by muse, mutect2, varscan2
- ANKIB1 | c.1995A>T p.P665= | Silent (SNP) | VAF 45/166 reads (27%) | catalogued as COSV56062333; called by muse, mutect2, varscan2
- ASXL3 | c.5592C>A p.G1864= | Silent (SNP) | VAF 84/326 reads (26%) | catalogued as COSV52468287; called by muse, mutect2, varscan2
- BRCA2 | c.6762T>C p.F2254= | Silent (SNP) | VAF 56/185 reads (30%) | catalogued as COSV104430694, COSV66455067; called by muse, mutect2, varscan2
- BRI3 | c.369C>G p.T123= | Silent (SNP) | VAF 29/104 reads (28%) | catalogued as COSV50054993, COSV50056662; called by muse, mutect2, varscan2
- C1QB | c.459C>T p.P153= | Silent (SNP) | VAF 11/108 reads (10%) | catalogued as COSV59245501; called by muse, mutect2, varscan2
- C5AR1 | c.138C>T p.V46= | Silent (SNP) | VAF 10/124 reads (8%) | catalogued as rs752136515, COSV61892705; called by muse, mutect2
- CDH10 | c.1170G>T p.L390= | Silent (SNP) | VAF 14/73 reads (19%) | catalogued as COSV100052524, COSV52571036; called by muse, mutect2, varscan2
- CDK19 | c.1458G>T p.S486= | Silent (SNP) | VAF 25/89 reads (28%) | catalogued as rs370278585, COSV60449988; called by muse, mutect2, varscan2
- CRACD | c.2346C>A p.P782= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as COSV51722587, COSV99949655; called by muse, mutect2, varscan2
- CYP4F3 | c.684C>A p.L228= | Silent (SNP) | VAF 34/314 reads (11%) | catalogued as COSV55409085, COSV55410586; called by muse, mutect2, varscan2
- DIDO1 | c.3645G>A p.R1215= | Silent (SNP) | VAF 41/264 reads (16%) | catalogued as COSV56624920; called by muse, mutect2, varscan2
- DIDO1 | c.1860G>T p.A620= | Silent (SNP) | VAF 99/181 reads (55%) | catalogued as COSV56624934; called by muse, mutect2, varscan2
- DYRK3 | c.1395G>T p.V465= | Silent (SNP) | VAF 53/298 reads (18%) | catalogued as rs782522977, COSV100895769; called by muse, mutect2, varscan2
- ECT2 | c.2679C>T p.V893= (on ENST00000392692 / NM_001349098.2; = p.V862= on NM_018098.6 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 21/218 reads (10%) | catalogued as COSV51689780; called by muse, mutect2
- ERC2 | c.2505G>T p.A835= | Silent (SNP) | VAF 44/197 reads (22%) | catalogued as rs375928296, COSV55628375; called by muse, mutect2, varscan2
- ERICH3 | c.885G>T p.G295= | Silent (SNP) | VAF 22/88 reads (25%) | catalogued as COSV58607790, COSV58609116; called by muse, mutect2, varscan2
- ERICH6 | c.1923T>G p.L641= | Silent (SNP) | VAF 62/155 reads (40%) | catalogued as COSV55801059; called by muse, mutect2, varscan2
- FAM135B | c.2967G>T p.V989= | Silent (SNP) | VAF 7/117 reads (6%) | catalogued as COSV52730301; called by muse, mutect2
- FEZF1 | c.477C>T p.A159= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV58658481, COSV58658967; called by muse, mutect2
- FILIP1 | c.3291G>A p.V1097= | Silent (SNP) | VAF 22/161 reads (14%) | catalogued as COSV52732120; called by muse, mutect2, varscan2
- FLNC | c.1650G>T p.T550= | Silent (SNP) | VAF 66/166 reads (40%) | catalogued as rs754474889, COSV57954944, COSV57957190; called by muse, mutect2, varscan2
- FUBP3 | c.306G>T p.R102= | Silent (SNP) | VAF 7/72 reads (10%) | catalogued as COSV60514604; called by muse, mutect2, varscan2
- HTR1A | c.582C>A p.G194= | Silent (SNP) | VAF 58/239 reads (24%) | catalogued as COSV60501204; called by muse, mutect2, varscan2
- HTR1E | c.1026G>T p.L342= | Silent (SNP) | VAF 16/186 reads (9%) | catalogued as COSV59508506; called by muse, mutect2
- HTRA2 | c.12G>A p.P4= | Silent (SNP) | VAF 15/96 reads (16%) | catalogued as COSV51206105, COSV99239704; called by muse, mutect2, varscan2
- IGSF11 | c.414C>T p.L138= (on ENST00000393775 / NM_001015887.3; = p.L137= on NM_152538.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/87 reads (10%) | catalogued as COSV61168974; called by muse, mutect2, varscan2
- ITIH5 | c.252G>A p.E84= | Silent (SNP) | VAF 15/94 reads (16%) | catalogued as COSV56906214; called by muse, mutect2, varscan2
- KCNC2 | c.963G>T p.V321= | Silent (SNP) | VAF 17/79 reads (22%) | catalogued as COSV54370399; called by muse, mutect2, varscan2
- KIF26A | c.1380G>T p.G460= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV59467293; called by muse, mutect2, varscan2
- KIRREL2 | c.1995C>A p.P665= | Silent (SNP) | VAF 24/161 reads (15%) | catalogued as COSV99384181; called by muse, mutect2, varscan2
- KLHL22 | c.702G>T p.L234= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as rs1384437896, COSV61021365; called by mutect2, varscan2
- MCRS1 | c.660G>T p.V220= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV100657389; called by muse, mutect2, varscan2
- MEI1 | c.2598G>A p.L866= | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as COSV55903698; called by muse, mutect2, varscan2
- MOSPD3 | c.66G>T p.R22= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as rs756340667, COSV56158307; called by muse, mutect2, varscan2
- MYT1L | c.1084C>A p.R362= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as COSV101221046; called by muse, mutect2, varscan2
- NBN | c.1458T>C p.S486= | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as COSV55373665; called by muse, mutect2, varscan2
- NCAN | c.2370G>A p.L790= | Silent (SNP) | VAF 11/94 reads (12%) | catalogued as COSV53052388, COSV53055021; called by muse, mutect2, varscan2
- NOD2 | c.1923C>A p.A641= | Silent (SNP) | VAF 19/81 reads (23%) | catalogued as COSV56051608; called by muse, mutect2, varscan2
- NOS3 | c.1344C>A p.I448= | Silent (SNP) | VAF 30/117 reads (26%) | catalogued as COSV52486548, COSV52490812; called by muse, mutect2, varscan2
- NPAP1 | c.81C>A p.P27= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as COSV100275707; called by muse, mutect2
- NWD1 | c.2502C>A p.A834= | Silent (SNP) | VAF 12/85 reads (14%) | catalogued as COSV60343852; called by muse, mutect2, varscan2
- OR2T1 | c.498C>T p.P166= | Silent (SNP) | VAF 6/78 reads (8%) | catalogued as COSV63542134; called by muse, mutect2
- OR8U1 | c.357C>A p.A119= | Silent (SNP) | VAF 19/171 reads (11%) | catalogued as COSV100164018; called by muse, mutect2, varscan2
- OVGP1 | c.1803G>T p.V601= | Silent (SNP) | VAF 16/102 reads (16%) | catalogued as COSV100868221, COSV63859630; called by muse, mutect2, varscan2
- PCDH19 | c.2571G>T p.G857= (on ENST00000373034 / NM_001184880.2; = p.G810= on NM_020766.3) | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as rs1480768621, COSV55264679; called by muse, mutect2, varscan2
- PCDH7 | c.2385G>C p.A795= | Silent (SNP) | VAF 18/82 reads (22%) | called by muse, mutect2, varscan2
- PIK3CG | c.798C>T p.S266= | Silent (SNP) | VAF 14/89 reads (16%) | catalogued as rs772923587, COSV100782462, COSV63249226; called by muse, mutect2, varscan2
- PNMT | c.228C>T p.I76= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as rs766530928, COSV54093219; called by mutect2, varscan2
- PRLR | c.1482G>T p.L494= | Silent (SNP) | VAF 25/182 reads (14%) | catalogued as COSV51496545; called by muse, varscan2
- RIT2 | c.84A>G p.A28= | Silent (SNP) | VAF 47/168 reads (28%) | catalogued as COSV56301337; called by muse, varscan2
- RNF207 | c.1371G>T p.S457= | Silent (SNP) | VAF 12/77 reads (16%) | catalogued as COSV65007785; called by muse, mutect2, varscan2
- SARM1 | c.483G>T p.A161= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as COSV50229476; called by muse, mutect2
- SATB2 | c.213C>G p.G71= | Silent (SNP) | VAF 26/159 reads (16%) | catalogued as COSV53485401; called by muse, mutect2, varscan2
- SLC4A10 | c.1590G>T p.L530= (on ENST00000446997 / NM_001354461.2; = p.L500= on NM_022058.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV55782477; called by muse, mutect2, varscan2
- SLC9A5 | c.768C>T p.A256= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs753616217, COSV55362527; called by mutect2, varscan2
- SNX9 | c.447C>A p.G149= | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as COSV67584601; called by muse, mutect2, varscan2
- SPO11 | c.342C>A p.I114= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV61995949; called by muse, mutect2
- SPOCK3 | c.435C>A p.V145= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as COSV62727648; called by muse, varscan2
- STRC | c.4356A>T p.P1452= | Silent (SNP) | VAF 18/76 reads (24%) | catalogued as rs1460054514, COSV55852697; called by muse, mutect2, varscan2
- TNN | c.153C>A p.P51= | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as COSV53427955; called by muse, mutect2, varscan2
- TNXB | c.4860G>T p.P1620= (on ENST00000647633; = p.P1373= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/93 reads (28%) | catalogued as rs369139181, COSV64480378; called by muse, mutect2, varscan2
- TTC7B | c.1986G>T p.S662= | Silent (SNP) | VAF 29/88 reads (33%) | catalogued as COSV60632482; called by muse, mutect2, varscan2
- ZFP90 | c.879T>C p.H293= | Silent (SNP) | VAF 18/114 reads (16%) | catalogued as COSV68051003; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73846653 C>A | 5'Flank (SNP) | VAF 14/50 reads (28%) | called by muse, mutect2, varscan2
- AL590867.2 | n.77G>A | RNA (SNP) | VAF 12/111 reads (11%) | catalogued as rs746155606; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65500919 del TTT | 5'Flank (DEL) | VAF 9/64 reads (14%) | called by mutect2, pindel, varscan2
- ATP2B2 | c.*259G>T | 3'UTR (SNP) | VAF 16/68 reads (24%) | catalogued as COSV59498207; called by muse, mutect2, varscan2
- EPHA10 | c.850+17G>T | Intron (SNP) | VAF 19/102 reads (19%) | catalogued as COSV100140038; called by muse, mutect2, varscan2
- GBA3 | c.59-8265G>A | Intron (SNP) | VAF 24/276 reads (9%) | called by muse, mutect2
- PIK3CD | c.-138+2624T>A | Intron (SNP) | VAF 13/82 reads (16%) | catalogued as rs894169046, COSV66098769; called by muse, mutect2, varscan2
- ZNF271P | n.2184G>T | RNA (SNP) | VAF 15/63 reads (24%) | called by muse, mutect2, varscan2
